Somatic mutation profile of tumor specimen MP2PRT-PARUSF-TMP1-A (aliquot MP2PRT-PARUSF-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PARUSF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.4 years (3,082 days).
Specimen MP2PRT-PARUSF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bfe66a3-c634-4eb2-bd74-bbe68177b373.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARUSF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARUSF-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab0ddae8-8ff2-4937-aecb-122011aca06a

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 7, Silent 6, Frame Shift Ins 3, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 118/321 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP8B2 | c.3393G>A p.T1131= (on ENST00000672630; = p.T1098= on NM_001367934.1 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 143/356 reads (40%) | catalogued as rs141598097, COSV63831046; called by muse, mutect2
- ETV6 | c.1039_1040insCT p.Q347Pfs*25 | Frame Shift Ins (INS) | VAF 172/381 reads (45%) | catalogued as COSV56766345; called by mutect2, pindel*, varscan2*
- FSIP2 | c.5208A>T p.K1736N | Missense Mutation (SNP) | VAF 99/233 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV58090955; called by muse, mutect2, varscan2
- IGHV4-34 | c.101del p.G34Afs*5 | Frame Shift Del (DEL) | VAF 103/324 reads (32%) | catalogued as rs766338115; called by mutect2, pindel, varscan2
- NPS | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 142/416 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs986285118, COSV67690790; called by muse, mutect2
- PADI4 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs370710302; called by muse, mutect2, varscan2
- UNC80 | c.9482C>T p.A3161V | Missense Mutation (SNP) | VAF 138/387 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); catalogued as rs368594548; called by muse, mutect2, varscan2
- XKR6 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 138/351 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as rs201821196; called by muse, mutect2, varscan2
- CHD7 | c.6580_6581insTGGAA p.E2194Vfs*23 | Frame Shift Ins (INS) | VAF 166/502 reads (33%) | called by mutect2, pindel, varscan2
- CMTR1 | c.1385_1386insG p.V463Sfs*4 | Frame Shift Ins (INS) | VAF 160/398 reads (40%) | called by mutect2, pindel*, varscan2
- MRPL37 | c.1089C>A p.D363E | Missense Mutation (SNP) | VAF 177/482 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SETD2 | c.4443_4446del p.Y1481* | Frame Shift Del (DEL) | VAF 78/180 reads (43%) | called by pindel, varscan2
- ADAMTS18 | c.234C>T p.H78= | Silent (SNP) | VAF 168/430 reads (39%) | catalogued as rs369294701; called by muse, mutect2, varscan2
- FAM217A | c.1107G>A p.R369= | Silent (SNP) | VAF 97/275 reads (35%) | catalogued as COSV99212823; called by muse, mutect2, varscan2
- NUAK2 | c.477C>T p.I159= | Silent (SNP) | VAF 168/390 reads (43%) | catalogued as rs953753078; called by muse, mutect2, varscan2
- TOPAZ1 | c.81G>A p.A27= | Silent (SNP) | VAF 236/564 reads (42%) | called by muse, mutect2, varscan2
- TTC28 | c.7335G>A p.P2445= | Silent (SNP) | VAF 256/598 reads (43%) | catalogued as rs771522552, COSV67424825; called by muse, varscan2
- USH2A | c.14916C>T p.R4972= | Silent (SNP) | VAF 175/425 reads (41%) | catalogued as rs774031723, COSV56353429; called by muse, mutect2, varscan2
